TARGET case TARGET-30-PAUFVW — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5acc73f5-1483-5b56-8b67-ff66f8905204

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C49.4; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Classification of tumor: primary; Age at diagnosis: 6.8 years (2,489 days); Year of diagnosis: 2011; Days to last follow up: 2,769 days (7.6 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 3; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ALTE05N1.
   Treatment given: Protocol identifier: ANBL0532.

Follow-up (2 entries)
- Days to follow up: 2,374 days (6.5 years); Days to first event: 2,374 days (6.5 years); First event: Event.
- Days to follow up: 2,769 days (7.6 years); Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAUFVW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAUFVW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 2769
- Protocol: ANBL00B1, ANBL0532, ANBL0032, ALTE05N1
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
